Gene-level copy-number profile of tumor specimen C3N-03042-04 from CPTAC case C3N-03042, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 67.3 years (24,572 days).
Specimen C3N-03042-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e4115728-953e-422c-a6da-8483161e5182.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03042-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/d4522ce8-6fff-46c2-9bb4-236da8831589

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,700; copy number 2: 48,715; copy number 3: 1,105; copy number 4: 1,692; copy number 5: 108; copy number 9: 14; copy number 13: 4; copy number 20: 23.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,246,755–43,284,806, 7 genes: AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr11:90,017,611–90,075,096, 7 genes: AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 149 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,048,932–70,436,584, 41 genes, copy number 9–20: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr22:20,689,929–21,982,813, 78 genes, copy number 5 (broad region; genes not listed).
- chr22:24,011,192–24,774,720, 30 genes, copy number 5: CABIN1, AC253536.3, SUSD2, GGT5, GGTLC4P, POM121L9P, BCRP1, AP000354.1, SPECC1L, SPECC1L-ADORA2A, ADORA2A, ADORA2A-AS1, UPB1, AP000355.1, GUCD1, SNRPD3, AP000356.5, LRRC75B, GGT1, AP000356.1, BCRP3, AP000356.4, AP000356.3, AP000356.2, POM121L10P, ARL5AP4, AP000357.1, AP000358.1, CRIP1P4, PIWIL3.

Autosomal genes at a single copy (total copy number 1): 6,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
